Somatic mutation profile of tumor specimen C3L-00789-01 (aliquot CPT0016030017) from CPTAC case C3L-00789, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 31.5 years (11,520 days).
Specimen C3L-00789-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02982380-9b75-4d43-8dcb-3b2992e8da24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00789-31 (Blood Derived Normal), aliquot CPT0018330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e11d1d2b-b155-4aa9-a4fb-a29294076e54

The open-access MAF lists 37 somatic variants for this specimen: 30 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 5, Frame Shift Del 3, Nonsense Mutation 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.350G>A p.W117* | Nonsense Mutation (SNP) | VAF 58/227 reads (26%) | hotspot (GDC flag); catalogued as rs1559428056, CM141838, CM961425, COSV56542825, COSV56544265, COSV56548887; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AHDC1 | c.2227C>T p.R743W | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751160000, COSV55942078; called by muse, mutect2, varscan2
- C10orf95 | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs143763976; called by muse, mutect2, varscan2
- CCIN | c.65G>A p.R22K | Missense Mutation (SNP) | VAF 80/422 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs867238115; called by muse, mutect2, varscan2
- GCKR | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs376864764; called by muse, mutect2, varscan2
- KNL1 | c.1054A>G p.T352A (on ENST00000346991 / NM_170589.5; = p.T326A on NM_144508.5) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1244171225; called by muse, mutect2, varscan2
- NR4A1 | c.1724A>G p.Y575C | Missense Mutation (SNP) | VAF 53/265 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs750197047; called by muse, mutect2, varscan2
- OR4C12 | c.448G>T p.G150* | Nonsense Mutation (SNP) | VAF 54/233 reads (23%) | catalogued as COSV58860448, COSV58860591; called by muse, mutect2, varscan2
- STK31 | c.789G>C p.M263I | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100669573; called by muse, mutect2
- TTLL13P | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 53/290 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.164); catalogued as rs915335137; called by muse, mutect2, varscan2
- UGT1A3 | c.740A>G p.D247G | Missense Mutation (SNP) | VAF 55/247 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as rs1305518931; called by muse, mutect2, varscan2
- ALAS2 | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 91/321 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CDKN2C | c.332C>A p.A111D | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHD2 | c.1008_1011del p.K336Nfs*2 | Frame Shift Del (DEL) | VAF 23/124 reads (19%) | called by mutect2, pindel, varscan2
- HOXC5 | c.226T>C p.C76R | Missense Mutation (SNP) | VAF 58/256 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KDM5A | c.1236T>A p.D412E | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1210 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- MED4 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- MUC4 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- NDUFS2 | c.859G>T p.G287C | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OLFM4 | c.401T>C p.L134P | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- PARD6B | c.940A>T p.T314S | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PBRM1 | c.2606_2612del p.Q869Lfs*44 | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | called by mutect2, pindel, varscan2
- PPP1R9B | c.2127G>T p.L709F | Missense Mutation (SNP) | VAF 66/323 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- RAB3IL1 | c.968A>T p.H323L | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.113); called by muse, mutect2
- RASEF | c.578G>C p.R193T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SBF1 | c.3922del p.R1308Gfs*17 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel
- TTN | c.75758G>T p.G25253V (on ENST00000591111; = p.G17829V on NM_003319.4) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- WAS | c.1417G>C p.V473L | Missense Mutation (SNP) | VAF 85/396 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ZNF257 | c.74A>T p.Q25L | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATP6V1C2 | c.1035G>A p.L345= (on ENST00000272238 / NM_001039362.2; = p.L299= on NM_144583.4) | Silent (SNP) | VAF 62/323 reads (19%) | called by muse, mutect2, varscan2
- BTBD3 | c.960C>A p.I320= | Silent (SNP) | VAF 57/215 reads (27%) | called by muse, mutect2, varscan2
- KCNT2 | c.877C>A p.R293= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV54095385; called by muse, mutect2, varscan2
- TAF3 | c.849T>A p.T283= | Silent (SNP) | VAF 49/192 reads (26%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.750G>C p.L250= | Silent (SNP) | VAF 19/467 reads (4%) | called by muse, mutect2
- MED13L | c.-17C>A | 5'UTR (SNP) | VAF 82/376 reads (22%) | called by muse, mutect2, varscan2
- TGIF1 | c.-260C>T | 5'UTR (SNP) | VAF 40/136 reads (29%) | called by muse, mutect2, varscan2
